Gene-level copy-number profile of tumor specimen TCGA-BR-A44T-01A from TCGA case TCGA-BR-A44T, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 53.1 years (19,407 days).
Specimen TCGA-BR-A44T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.35d70fbe-6f9b-4aa5-b6c8-cb9e362d39be.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,551 have no estimate.
https://portal.gdc.cancer.gov/files/0291d616-3edd-4889-9b89-f8c9cc82b2b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 162; copy number 2: 56,760; copy number 3: 48; copy number 4: 26; copy number 5: 15; copy number 6: 24; copy number 7: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A44T-01A-32D-A24C-01): tumor purity 0.64, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:34,105,617–35,585,310, 26 genes, copy number 5–7: NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1.
- chr11:35,662,775–35,838,523, 2 genes, copy number 5 (within-gene range 2–5): TRIM44, AC090692.2.
- chr11:35,943,981–36,232,136, 1 gene, copy number 5 (within-gene range 4–7): LDLRAD3.
- chr11:36,010,098–36,465,204, 6 genes, copy number 5–7 (within-gene range 2–7): MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2.
- chr11:37,938,601–38,212,799, 3 genes, copy number 5: LINC02760, AC103798.1, LRRC6P1.
- chr12:68,746,125–68,971,570, 10 genes, copy number 7: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,422,656–70,637,440, 24 genes, copy number 6: RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,906,917–71,118,247, 4 genes, copy number 5–7: Y_RNA, AC123905.1, AC025575.1, AC025575.2.

Autosomal genes at a single copy (total copy number 1): 162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
